Somatic mutation profile of tumor specimen TCGA-QR-A6H6-01A (aliquot TCGA-QR-A6H6-01A-11D-A35D-08) from TCGA case TCGA-QR-A6H6, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 27.9 years (10,180 days).
Specimen TCGA-QR-A6H6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd3a09e6-40e6-434e-9596-5ac72fd54afd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A6H6-10A (Blood Derived Normal), aliquot TCGA-QR-A6H6-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87ad37a7-b9ed-42c7-9d71-c389d0d737a0

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCAF8 | c.3370C>T p.R1124W | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.874); catalogued as rs754810889, COSV65791583; called by muse, mutect2, varscan2
- STK11IP | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1316287895, COSV99822090; called by muse, mutect2, varscan2
- GOLGA1 | c.919C>G p.L307V | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- NUMA1 | c.6032del p.P2011Hfs*4 | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | called by mutect2, pindel, varscan2
- ZSCAN31 | c.671G>A p.S224N | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- COL21A1 | c.273C>T p.L91= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs182718262, COSV55156646, COSV99780013; called by muse, mutect2, varscan2
- FKBP8 | c.843G>A p.S281= (on ENST00000222308 / NM_001308373.2; = p.S282= on NM_012181.5) | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as rs146804732; called by muse, mutect2, varscan2
